Gene-level copy-number profile of tumor specimen TCGA-DX-A6B8-01A from TCGA case TCGA-DX-A6B8, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Liposarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 80.8 years (29,513 days).
Specimen TCGA-DX-A6B8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.28b602f2-2fc5-4c5e-a7dd-91c7927658f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A6B8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/922205f1-5f07-4eb1-9e69-daa926366f3e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 162; copy number 1: 3; copy number 2: 9; copy number 3: 3,916; copy number 4: 25,546; copy number 5: 1,904; copy number 6: 10,722; copy number 7: 3,308; copy number 8: 12,775; copy number 9: 267; copy number 10: 38; copy number 11: 359; copy number 12: 643; copy number 13: 8; copy number 14: 22; copy number 15: 94; copy number 23: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A6B8-01A-11D-A306-01): tumor purity 0.91, ploidy 1.53, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 162 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:134,465–689,668, 10 genes: ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26.
- chr10:34,109,560–34,815,325, 3 genes (within-gene range 0–4): PARD3, Y_RNA, ELOBP4.
- chr10:86,668,507–89,063,411, 74 genes (within-gene range 0–4) (broad region; genes not listed).
- chr12:94,140,077–94,141,337, 1 gene: AC123567.1.
- chr12:94,167,528–94,187,724, 1 gene: AC123567.2.
- chr16:35,090,501–35,912,516, 73 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,420 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:68,679,601–68,826,833, 1 gene, copy number 11 (within-gene range 4–11): ARHGAP25.
- chr4:51,843,000–89,999,409, 619 genes, copy number 12 (broad region; genes not listed).
- chr4:90,370,123–90,370,427, 1 gene, copy number 12: RN7SKP248.
- chr4:143,497,412–145,098,174, 20 genes, copy number 12 (within-gene range 8–12): AC104685.1, SMARCA5-AS1, SMARCA5, AC139713.1, AC107223.1, GUSBP5, FREM3, AC104090.1, GYPE, AC093890.1, GYPB, AC093890.2, GYPA, AC098588.3, AC098588.2, AC106871.1, KRT18P51, HHIP-AS1, HHIP, AC098588.1.
- chr4:144,845,625–144,921,164, 3 genes, copy number 12: HSPD1P5, AC109811.1, AC109811.2.
- chr5:121,961,975–123,423,592, 26 genes, copy number 9: SRFBP1, LOX, AC010255.1, ZNF474, AC010255.2, ZNF474-AS1, AC113349.2, SNCAIP, AC113349.1, AC119150.1, AC119150.2, MGC32805, LINC02201, ARGFXP1, SNX2, AC008669.1, SNX24, RN7SL689P, PPIC, PPIC-AS1, RN7SL711P, AC106786.1, PRDM6, AC010493.1, CEP120, KRT8P33.
- chr5:126,179,565–126,193,858, 1 gene, copy number 9: LINC02039.
- chr5:131,155,383–131,398,447, 4 genes, copy number 9 (within-gene range 6–9): HINT1, LYRM7, CDC42SE2, AC004777.1.
- chr5:136,734,830–137,761,936, 9 genes, copy number 9 (within-gene range 6–9): AC109439.1, ANKRD49P3, RNA5SP193, SPOCK1, KLHL3, MIR874, HNRNPA0, AC106791.3, AC106791.2.
- chr5:140,107,777–140,828,549, 40 genes, copy number 9 (within-gene range 6–9): PURA, IGIP, AC011379.2, CYSTM1, AC011379.1, PFDN1, HBEGF, AC008438.2, SLC4A9, AC008438.1, RNU4-14P, ANKHD1, ANKHD1-EIF4EBP3, AC011399.1, SRA1, EIF4EBP3, APBB3, AC116353.5, MIR6831, SLC35A4, AC116353.6, AC116353.1, HAUS1P1, AC116353.2, CD14, NDUFA2, TMCO6, IK, MIR3655, WDR55, DND1, HARS1, HARS2, ZMAT2, VTRNA1-1, VTRNA1-2, VTRNA1-3, AC116353.4, AC116353.3, AC005609.5.
- chr11:103,045,237–103,092,194, 3 genes, copy number 10: AP001486.1, DCUN1D5, AP001486.2.
- chr13:110,613,082–114,337,626, 94 genes, copy number 15 (broad region; genes not listed).
- chr14:21,887,857–23,435,660, 175 genes, copy number 9 (broad region; genes not listed).
- chr14:37,896,060–40,390,547, 32 genes, copy number 10: LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1, AL357094.1, KRT8P1, LINC00639, AL132994.1, AL132994.2, Y_RNA, SEC23A, AL109628.1, SEC23A-AS1, PPIAP4, GEMIN2, TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN, AL132639.1, YTHDF2P1, MIA2, AL132639.2, GLRX5P3, COILP1, FBXO33, AL049828.1, AL049828.2.
- chr17:15,062,087–22,706,703, 392 genes, copy number 11–23 (within-gene range 8–23) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
